Surgical pathology report (de-identified scan), TCGA case TCGA-G5-6641, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G5-6641-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. SIGMOID COLON AND UPPER RECTUM
- B. DISTAL DONUT
- C. PROXIMAL DONUT

SPECIMEN(S):

- A. SIGMOID COLON AND UPPER RECTUM
- B. DISTAL DONUT
- C. PROXIMAL DONUT

GROSS DESCRIPTION:

A. RECTOSIGMOID COLON

Received fresh is 7.5 cm segment of colon with a circumference of 6.2 cm. The proximal surgical margin is stapled and the distal (designated by a suture) is received opened. Located 1.3 cm from the distal margin is a polypoid tumor mass measuring 2 x 1.3 x 0.8 cm. The remainder of the mucosa is free of masses or lesions. The distal margin is inked blue. The specimen is sectioned and the mass appears to have superficial invasion. Tissue is procured; a photograph is taken. Representatively submitted in:

A1: shave of proximal margin

A2-A6: entire mass including distal margin (perpendicular sections) and deep margin

A7: normal-appearing mucosa

A8-A14: lymph nodes

B. COLON DISTAL MARGIN

Received in formalin is a donut of pink-tan mucosa, 2.5 x 2.3 x 1.1 cm. Specimen is held intact by staples. The mucosa has pinpoint areas of hemorrhage. After removal of staples specimen is submitted entirely in cassette B1.

C. COLON PROXIMAL MARGIN

Received in formalin is a donut of pink-tan mucosa, 1.9 x 1.7 x 1.2 cm. It is held intact by blue suture material. The mucosa is unremarkable. The specimen is submitted entirely in cassette C1.

DIAGNOSIS:

a. RECTOSigmoid colon, LOW ANTERIOR RESECTION:

- INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH PROMINENT MUCINOUS FEATURES (MUCINOUS ADENOCARCINOMA) INVADING SUBMUCOSA AND ASSOCIATED WITH VILLOGLANDULAR ADENOMA
- TUMOR SIZE 2 X 1.3 CM
- METASTATIC CARCINOMA TO ONE OUT OF TWENTY SIX lymph nodeS (1/26) WIT FOCAL EXTRANODAL EXTENSION
- MARGINS Negative FOR CARCINOMA
- see synaptic REPORT

b. colon, distal MARGIN, excision:

- colonic tissue, NO CARCINOMA SEEN

c. colon, PROXIMAL MARGIN, excision:

- colonic tissue, NO CARCINOMA SEEN

SYNOPTIC REPORT - COLON & RECTUM

Specimen Type: Rectal/rectosigmoid colon (low anterior resection)

Tumor Site: Rectosigmoid

Tumor Configuration: Exophytic (polypoid)

Infiltrative

Tumor size: 2cm Additional dimensions 1.3cm x 0.8cm

WHO Classification

Adenocarcinoma 8140/3

Comment(s): with mucinous features (mucinous adenocarcinoma)

Histologic Grade: G2: Moderately differentiated

Extent of Invasion: Submucosa

Margins: Margin(s) uninvolved by invasive carcinoma (Proximal, Distal, Radial)

Venous/Lymphatic Invasion: Indeterminate

Comment(s): No definite lymphovascular invasion seen in the tumor tissue sections.

Perineural Invasion: Absent

[page 2 of 2]
Additional Pathologic Findings: None identified
Extent of Resection: R0: Complete resection with grossly and microscopically negative margins
Lymph Nodes: Positive 1 / 26
Extranodal extension: Present
Implants: Absent
Pathological Staging (pTNM): pT 1 N 1 M x

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Rectosigmoid cancer

Source: NCI Genomic Data Commons file 4e89e4c0-73cf-4a08-9778-efb8f2d22ef0 (TCGA-G5-6641.7BB08AAD-D471-4309-BB5E-E6F1FE2405A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).